CCDI case PBCMZF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/16df2988-1981-4c0a-93ad-b941db6ffccd

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.2 years (5,548 days).

Biospecimens (3 samples)
- Sample 0DVPN7: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVPOW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DVPPA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
